Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A416, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A416-01A (Primary Tumor).

Procurement Date: Lateralities: Tumor consists of papillae having an fine fibrovascular stalk covered by a single to mutiple layers of cuboidal epithelial cells. Tumor invades in capsule or vessle or beginn tissue or muscle. The cells tend to maintain their polarity. Nulei are quite regular and contain finely dispersed chromatin, or intranuclear grooves. Tumor is fibrous and invasion of lymphocytes.

Path Report: Tumor type: Papillary carcinoma

Tumor size: 1.5x1x1cm

Lateralities: left

Focality: Unifocal

Extension beyond capsule: Not specified

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, Nos

C73.9

7-20-12 RD

Reviewed (initials):	Date Reviewed: 7/16/12	

Source: NCI Genomic Data Commons file 6a123704-e7fc-4226-aaf1-8c08262084a8 (TCGA-E8-A416.EC98D84D-CD30-4F1A-A262-2D835764A111.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).